Somatic mutation profile of tumor specimen MP2PRT-PAVYDP-TMP1-A (aliquot MP2PRT-PAVYDP-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYDP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,471 days).
Specimen MP2PRT-PAVYDP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8c5453-a971-4a41-8440-47e68a01d448.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYDP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYDP-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bd8c7d8-53fc-41ab-bf51-68c182d3d940

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 26/468 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2
- CRYGC | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 155/378 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs368393196; called by muse, mutect2, varscan2
- FAM76B | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 182/475 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57690314; called by muse, mutect2, varscan2
- INSL3 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 223/467 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as rs199517316, COSV100427608; called by muse, mutect2, varscan2
- KIF21B | c.3628C>T p.R1210* | Nonsense Mutation (SNP) | VAF 136/404 reads (34%) | catalogued as COSV100143265; called by muse, mutect2, varscan2
- KMT2C | c.8626G>A p.D2876N | Missense Mutation (SNP) | VAF 173/409 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100074853; called by muse, mutect2, varscan2
- MAGEC1 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 28/661 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV104375451; called by muse, mutect2
- MROH2A | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 145/420 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1042908100; called by muse, mutect2, varscan2
- NID1 | c.2518G>A p.V840M | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs771612950, COSV51629859; called by muse, mutect2, varscan2
- NTN4 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 161/404 reads (40%) | catalogued as rs753730047, COSV59218605; called by muse, mutect2, varscan2
- SALL3 | c.3745G>A p.A1249T | Missense Mutation (SNP) | VAF 264/719 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as COSV73305973; called by muse, mutect2, varscan2
- TRPS1 | c.2974C>T p.H992Y (on ENST00000220888 / NM_001330599.2; = p.H1005Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/400 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV55249243; called by muse, mutect2, varscan2
- ADRA1D | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- CELF5 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGLV4-69 | c.355_359delinsCCCTC p.I119P | Missense Mutation (ONP) | VAF 79/169 reads (47%) | called by pindel, varscan2*
- LRRC66 | c.1270_1271dup p.F425Afs*26 | Frame Shift Ins (INS) | VAF 130/370 reads (35%) | called by pindel, varscan2
- MAGEC1 | c.2223G>C p.Q741H | Missense Mutation (SNP) | VAF 199/559 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MRPL19 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 116/416 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TRAPPC10 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 164/659 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UBN2 | c.1611A>C p.R537S | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ADO | c.84C>T p.R28= | Silent (SNP) | VAF 159/626 reads (25%) | catalogued as rs766375529; called by muse, mutect2
- IGFBP1 | c.199C>T p.L67= | Silent (SNP) | VAF 266/675 reads (39%) | catalogued as rs1260884428; called by muse, mutect2, varscan2
- PSAPL1 | c.378G>A p.P126= | Silent (SNP) | VAF 140/514 reads (27%) | catalogued as rs772342346, COSV100040512; called by muse, mutect2, varscan2
- HP1BP3 | c.-78A>C | 5'UTR (SNP) | VAF 120/314 reads (38%) | called by muse, mutect2, varscan2
